Surgical pathology report (de-identified scan), TCGA case TCGA-DH-A7UT, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Florida, specimen TCGA-DH-A7UT-01A (Primary Tumor).

[page 1 of 6]
THIS IS AN ADDENDUM REPORT ****

ICD-O-3
Astrocytoma, grade III 9461.1
Site ^{cereb} Brain, supratentorial No
path C71.0
D Brain NOS C71.1

JW 10/4/13

SPECIMEN(S) SUBMITTED / PROCEDURES ORDERED

A. Brain tumor A. Frozen Section Charge

A. Glial Fibrill. Acid Prt A. P53 Protein A.
Isocitrate dehydrogenase 1 A. KI-67, Nuclear Antigen, Mib1

A. Phosphohistone-H3 A. 1P19q Malignant
Glioma Anaysis A. 1P19q Malignant Glioma Analysis,
add x 3 B. Brain tumor C. Brain tumor

CLINICAL HISTORY: -old male with no significant past medical
history. Evaluate revealed left frontal brain tumor. Here today for
left stealth awake craniotomy.

DIAGNOSIS:

- A. "Brain tumor, left frontal, awake craniotomy for resection":
Anaplastic astrocytoma, WHO Grade III (see comment)
- B. "Brain tumor, left frontal, awake craniotomy for resection":
Anaplastic astrocytoma, WHO Grade III (see comment)
- C. "Brain tumor, left frontal, awake craniotomy for resection":
Anaplastic astrocytoma, WHO Grade III (see comment)

COMMENT: Sections show an infiltrating glioma with prominent nuclear and
cellular pleomorphism and non-uniformity and increased mitoses. No
definitive microvascular proliferation or necrosis is seen in this
material. Tumor cells and tumor cell processes are immunoreactive for

[page 2 of 6]
GFAP. The tumor is positive for mutated isocitrate dehydrogenase 1 (IDH-1). P53 is immunoreactive in numerous tumor cell nuclei (50% approximately). PHH3 confirms increased mitotic activity (up to 7 mitoses per 10 high power fields). Ki-67 confirms a focally elevated proliferation index (up to 8% approximately). These findings support the diagnosis.

has reviewed this case and concurs.

Molecular testing for 1p and 19q chromosome status has been ordered and results will follow in an addendum to this report.

NEUROPATHOLOGY TUMOR SUMMARY

Tumor Site

Brain / Cerebrum

Frontal

Laterality: Left

Procedure

Resection

Tumor

Anaplastic astrocytoma (WHO grade III)

Ancillary studies

Glioma ancillary studies

p53 IHC: Strongly positive: 50%

IDH-1 IHC: Positive

Ki-67 (MIB-1) IHC: Positive: 8%

PHH3 IHC: Positive cells/ 10 HPF: 7

Comment(s): 1p/19q testing is in progress and result will follow in an

[page 3 of 6]
GROSS DESCRIPTION: Received the following specimens in the
labeled with the patient's name and hospital #

A. Brain tumor

B. Brain tumor

C. Brain tumor

A. The specimen is received fresh, designated "Brain tumor" and consists of a 0.9 x 0.6 x 0.3 aggregate of pink to pink-tan soft tissue fragments. Representative sampling is submitted for frozen section. The resulting intraoperative diagnosis is "Infiltrating glioma. Grade deferred. . Frozen tissue is resubmitted for permanent processing in cassette FSA1 with the remaining tissue submitted entirely in cassette A2.

B. The specimen is received fresh, designated "Brain tumor" and consists of an unoriented, 3.5 x 2.8 x 1.5 cm portion of pink-tan to red, focally hemorrhagic soft tissue with apparent prominent vasculature on one surface. The specimen is serially sectioned and submitted entirely in cassettes B1 through B5 with a representative sampling also submitted to the tumor bank.

C. The specimen is received fresh, designated "Brain tumor" and consists of multiple irregular and varying-sized fragments of pink to pink-tan soft tissue, measuring 1.5 x 1.0 x 0.5 cm in aggregate. The specimen is entirely submitted in cassette C1.

"I, or my qualified designee, performed the gross examination. I have personally reviewed the gross description and performed a microscopic examination on all referenced material. I have personally issued this

[page 4 of 6]
report on the basis of the gross and microscopic findings."

Note: Test systems have been developed and their performance characteristics determined by Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

ADDENDUM:

CHROMOSOMES 1p / 19q FISH ANALYSIS-

RESULTS

Chromosome 1p: NON-DELETED

Chromosome 19q: NON-DELETED

INTERPRETATION

There are NO deletions of chromosomes 1p and 19q in the tissue analyzed.

References:

1. Cairncross JG, et al. Specific genetic predictors of chemotherapeutic response and survival in patients with anaplastic oligodendrogliomas. J Natl Cancer Inst 90:1473-1479, 1998.
2. Smith JS, et al. Alterations of chromosome arms 1p and 19q as predictors of survival in oligodendrogliomas, astrocytomas, and mixed oligoastrocytomas. J Clin Oncol 18:636-45, 2000.
3. Perry A. Ancillary fish analysis for 1p and 19q status: preliminary

[page 5 of 6]
observations in 287 gliomas and oligodendroglioma mimics. *Front Biosci* 8:a1-9, 2003.

4. McDonald JM, et al. The prognostic impact of histology and 1p/19q status in anaplastic oligodendroglial tumors. *Cancer*. 104:1468-77, 2005

5. Cairncross JG, et al. Phase III trial of chemotherapy plus radiotherapy compared with radiotherapy alone for pure and mixed anaplastic oligodendroglioma: Intergroup Radiation Therapy Oncology Group trial 9402. *J Clin Oncol*. 2006;24:2707-14.

Specimen

Anatomic site: Brain tumor, left frontal lobe

Test description

Reference range: 1p/ 19q: Non-deleted

-

A tumor is considered to have 1p or 19q deletion when the 1p probe to 1q probe ratio (1p/1q) or the 19q probe to 19p probe ratio (19q/19p) is

1.30. A tumor is considered to have chromosome 1 or 19 gain when the percentage of nuclei with ≥ 3 signals is $\geq 20\%$. A normal 1p/1q ratio is 0.9-1.05 and a normal 19q/19 p ratio is 0.93-1.02.

The test uses two dual-probe 1p36 probe combined with a control 1q probe and a 19q13.3 probe combined with a control 19p probe. Probes are specific to the minimally deleted regions of 1p (1p36) and 19q (19q13.3) to detect 1p and 19q deletion. The selection of tissue and the identification of target areas on the H&E stained slide is performed by a pathologist. The number of 1p and 19q signals in the area of interest is

[page 6 of 6]
scored. The testing was performed and performance characteristics of this

test were validated by the

It has not been cleared or approved by the FDA. This test is used for clinical purposes. It should

not be regarded as investigational or for research. This laboratory is

certified under the Clinical Laboratory Improvement Amendments to perform

high complexity clinical laboratory testing.

Pathologist

Source: NCI Genomic Data Commons file 785987e0-2947-47be-a3a3-67fc8ed043dd (TCGA-DH-A7UT.D737A708-EBF5-41F9-9245-7438F71891F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).